Surgical pathology report (de-identified scan), TCGA case TCGA-66-2781, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Indivumed, specimen TCGA-66-2781-01A (Primary Tumor).

[page 1 of 2]
Material examined:

Left upper lobe

Clinical diagnosis and question

Moderately differentiated, slightly keratinizing squamous cell carcinoma B3 left. Asbestos exposure.

REPORT ON FINDINGS**Macroscopy**

1.) Left upper lobe: inflated, fixed left upper lobe measuring 21 x 15.5 x 5 cm. Central bronchus resection plane located 0.1 cm proximal to the division into bronchi of the apical group and lingular bronchus. At the hilus six blackish pigmented nodes, 0.8 and 2.3 cm in size. A 7 cm long staple suture line runs from the hilus in a cranial direction, dorsal to the hilus runs an oblique 4 cm long staple suture line, and a third, slightly branched, 13 cm long staple suture line runs from the hilus in a caudodorsal direction. Apical pleura over S1 shows a 3 cm striated area of grayish discoloration, in parts with vaguely plate-shaped thickening. Centrally in the boundary region of S1-S3 is a firm whitish tumor, max. 3.6 cm in size, showing patches of blackish pigmentation and patches of pale yellow, with an unclear demarcation and the main mass in S2. B2 ending in the tumor. Polypous spread of tumor to the central section of B3, distance from central bronchus resection plane about 1 cm. Peripheral spread to within 0.2 cm of the medial, visceral pleura over S2. A narrow 0.6 cm blackish pigmented node at the first branch of B3 in the marginal area of the tumor. Rest of parenchyma of the upper lobe rarefied with the formation of lacunae of max. 0.3 cm. Below the thickening of apical pleura over S1 the parenchyma is compacted and pale in a seam up to 0.6 cm wide over an area of max. 4.5 cm.

2.) Lobar LN (station 12) lower lobe: 1.5 cm lesioned node.

3.) Hilar LN (station 10) left: 1.2 cm node sparse surrounding tissue.

4.) Paraaortic LN (station 6); 2.2 cm node with surrounding tissue.

5.) Subaortic LN (aortopulmonary window) (station 5): 0.9 cm node part.

b.) Subcarinal LN (station 7): 1.3 cm node with some surrounding tissue.

Examined:

1.) a: 2 sections of tumor with pleura.

1b: Tumor with endobronchial part in B3,

1c: 2 sections of tumor with node at the first bifurcation of B3,

1d: S1 apical with parenchymal compaction,

1e: 1 section S2.

1f: Bronchus and vessel resection margins (tangential),

1g and 1h: hilar nodes,

2.) - 6.) All material (in 4.) lamellated).

13 blocks, partly Elastica-van Gieson, PAS, diastase-PAS.

Microscopy

Description of histological and cytological findings omitted for capacity reasons.

[page 2 of 2]
EVALUATION

Primary diagnosis/diagnoses:

Primarily evident central to peripheral, bronchopulmonary, histologically poorly differentiated, large-cell, focal gigantocellular and slightly keratinizing squamous cell carcinoma of the left upper pulmonary lobe with main location in S2.

TNM classification according to this picture pT2 pN0pMX V1 R0 stage B. C34.1, M8070/3.

Secondary diagnosis/diagnoses:

Moderate centrocinar pulmonary emphysema. Focal intraalveolar accumulation of pigmented macrophages. Uncharacteristic subpleural cicatricial zone and moderate fibrous enlargement of the visceral pleura at the apex of the upper lobe (sample 1.)), lymph nodes with uncharacteristic and anthracotic pigment deposits (samples 1. to.)).

Remark/addendum:

The resection margin of bronchus and vessels, the visceral pleura and all excised and identified lymph nodes are tumor-free.

No asbestos bodies are found in the prepared section planes. But very much further-reaching investigations, especially dust analyses, are needed to determine the asbestos exposure of the lung.

Source: NCI Genomic Data Commons file d89629f8-5a37-4fa9-b367-f7788d5ea169 (TCGA-66-2781.4227EFE2-597D-4D53-91F5-73C3FA32F6F5.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).